Somatic mutation profile of tumor specimen TCGA-SP-A6QH-01A (aliquot TCGA-SP-A6QH-01A-21D-A35I-08) from TCGA case TCGA-SP-A6QH, project TCGA-PCPG (Pheochromocytoma and Paraganglioma). Sex at birth: female; Vital status: Alive; Primary diagnosis: Pheochromocytoma, NOS; Tissue or organ of origin: Adrenal gland, NOS; Age at diagnosis: 35.3 years (12,876 days).
Specimen TCGA-SP-A6QH-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 31bef652-d3ff-4159-9829-0541ba11c669.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-SP-A6QH-11A (Solid Tissue Normal), aliquot TCGA-SP-A6QH-11A-12D-A35G-08; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/813623ff-d868-4489-9322-84681d136feb

The open-access MAF lists 7 somatic variants for this specimen: 5 protein-altering or splice-affecting, 2 silent.
By variant classification: Missense Mutation 5, Silent 2.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- P2RX4 | c.952C>T p.R318C | Missense Mutation (SNP) | VAF 6/47 reads (13%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.894); catalogued as rs148705105; called by muse, mutect2, varscan2
- TMEM132E | c.949C>T p.R317W (on ENST00000321639; = p.R407W on NM_001304438.2) | Missense Mutation (SNP) | VAF 9/88 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs371393529, COSV58695340; called by muse, mutect2, varscan2
- PCDHGA7 | c.886T>C p.S296P | Missense Mutation (SNP) | VAF 7/31 reads (23%) | SIFT tolerated, low confidence (0.07); PolyPhen benign (0.013); called by muse, mutect2, varscan2
- SPIC | c.457C>A p.L153I | Missense Mutation (SNP) | VAF 4/50 reads (8%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.998); called by muse, mutect2
- ZBBX | c.1288G>T p.D430Y | Missense Mutation (SNP) | VAF 13/75 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (0.96); called by muse, mutect2, varscan2
- GPRASP1 | c.2970G>C p.G990= | Silent (SNP) | VAF 6/76 reads (8%) | called by muse, mutect2
- SYPL1 | c.348A>G p.Q116= | Silent (SNP) | VAF 14/66 reads (21%) | called by muse, mutect2, varscan2
